Somatic mutation profile of tumor specimen ALCH-B2QQ-TTP1-A (aliquot ALCH-B2QQ-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2QQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.9 years (19,705 days).
Specimen ALCH-B2QQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db17aed5-8975-4b82-bba3-98f61d250ad8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2QQ-NB1-A (Blood Derived Normal), aliquot ALCH-B2QQ-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da672057-9c73-4bca-b664-138f8aa71b3a

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITGA9 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 26/528 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.872); catalogued as rs368067046, COSV53240019; called by muse, mutect2
- PRNP | c.496A>G p.M166V | Missense Mutation (SNP) | VAF 66/1160 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776401404; called by muse, mutect2
- ETV1 | c.633C>A p.Y211* | Nonsense Mutation (SNP) | VAF 34/621 reads (5%) | called by muse, mutect2
- INVS | c.1150G>C p.D384H | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); called by muse, mutect2
- POT1 | c.390C>A p.H130Q | Missense Mutation (SNP) | VAF 74/868 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CSMD1 | c.5766C>T p.P1922= (on ENST00000520002; = p.P1921= on NM_033225.6) | Silent (SNP) | VAF 27/525 reads (5%) | catalogued as COSV59277901; called by muse, mutect2
- SEMA6B | c.327C>T p.N109= | Silent (SNP) | VAF 14/436 reads (3%) | called by muse, mutect2
